Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9Q1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9Q1-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

A: Subcutaneous mass, excision: Epidermal inclusion cyst.

B: Kidney, left, adrenal sparing nephrectomy:

- 1. Papillary renal cell carcinoma, type 2, grade 2, 4.6 cm, see comment.**
- 2. Simple renal cyst.**

COMMENT:

Kidney Tumor Synoptic Comment

- **Histologic type:** Renal cell carcinoma, papillary (chromophil) type.
- **Grade:** Fuhrman grading for RCC: grade 2.
- **Tumor size:** 4.6 cm.
- **Site within kidney:** Upper pole.
- **Renal pelvis:** Normal.
- **Ureter:** Normal.
- **Renal sinus:** Normal.
- **Hilar renal veins:** Normal.
- **Intrarenal veins and lymphatics:** Normal.
- **Adrenal gland:** Not present.
- **Capsule/perirenal fat:** Tumor does not penetrate capsule.
- **Lymph node status:** None present. The hilar fat was searched for lymph nodes and none were found.
- **Resection margins:** Negative.
- **Ureter:** >1cm.
- **Renal vein:** >1 cm.
- **Soft tissue:** Negative, 0.2 cm (see slide B9).
- **Renal parenchyma:** Negative, tumor is 0.2 cm from the renal parenchymal margin (see slide B7).
- **Proximity to nearest margin:** 0.2 cm.
- **AJCC Stage:** pT1bNxMx.

ICD 8-3
Carcinoma, papillary renal
cell 8260/3
Site: @ Kidney NOS c64.9
9/23/14

Specimen(s) Received

[page 2 of 2]
A:Subcutaneous mass
B:Left kidney (fresh)

Clinical History

The patient is an [REDACTED] female with a left kidney mass which is solid and cystic in the left upper pole. This lesion is greater than 5 cm. Additionally, there is a second lesion in the interpolar region. The patient also has a 2.4 cm lesion in the liver. She now undergoes a left laparoscopic nephrectomy ([REDACTED]).

Gross Description

The specimen is received fresh in two parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "subcutaneous mass," consists of three fragments of white and yellow soft tissue measuring 1.5 x 0.7 x 0.3 cm in aggregate. These fragments are entirely submitted in cassette A1.

Part B, additionally labeled "left kidney," consists of a 236 gram, 14 x 6 x 6 cm kidney with a small amount of perinephric fat. The superior pole has a 4.6 cm, red to yellow soft mass with solid and liquefied areas within 0.3 cm of the pelvis and abutting the renal capsule over much of the tumor. The tumor is suspicious for invasion into the renal capsule grossly. Additionally a second lesion is identified in the interpolar region of the kidney, which is entirely contained in the cortex and does not appear to invade. This lesion is composed of a cyst-like space measuring 2.4 cm. Cassettes are submitted as follows:

Cassette B1: Pelvic margin vessels and ureter.
Cassette B2: Pelvis with red to yellow mass.
Cassette B3: Cystic lesion to pelvis.
Cassette B4: Normal pelvis.
Cassette B5: Parenchyma with vessels.
Cassettes B6-B8: Tumor with capsule.
Cassettes B9-B10:

Extrarenal soft tissue.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]
Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 42ccc9af-3109-49da-b3f9-2fc45422b03c (TCGA-UZ-A9Q1.F7BB999F-7D85-4547-A65A-9409FD7C0CEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).